Gene-level copy-number profile of tumor specimen TCGA-DD-AADC-01A from TCGA case TCGA-DD-AADC, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 53.5 years (19,527 days).
Specimen TCGA-DD-AADC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.262b797a-e206-4879-9aab-86cb3f5fb4c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AADC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c142e4f6-54c8-4669-bdc0-01488112c4e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 16,382; copy number 2: 33,250; copy number 3: 6,549; copy number 4: 1,567; copy number 5: 1,467; copy number 6: 411; copy number 7: 128; copy number 10: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AADC-01A-11D-A40Q-01): tumor purity 0.71, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,035 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:213,924,749–214,187,773, 5 genes, copy number 5: LINC00538, PROX1, AC011700.1, AL606537.1, LINC02775.
- chr3:31,161,704–31,637,616, 6 genes, copy number 6: MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1, STT3B.
- chr3:32,030,196–36,548,007, 58 genes, copy number 5–6: RPL21P40, AC094019.1, Y_RNA, NIFKP7, GPD1L, AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1, AC018359.1, AC007483.1, FECHP1, KRT8P18, RNU6-243P, ARPP21, ARPP21-AS1, MIR128-2, AC104308.1, RFC3P1, STAC.
- chr3:90,030,284–90,261,708, 4 genes, copy number 5: U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:149,462,182–150,873,554, 40 genes, copy number 5: AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, AC018545.1, TSC22D2, SERP1, EIF2A, SELENOT, AC069236.1, ERICH6, ERICH6-AS1, SNRPCP3, AC011317.1, SIAH2, SIAH2-AS1.
- chr3:167,065,831–180,684,942, 202 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr4:132,591,064–134,010,690, 10 genes, copy number 5: LINC01256, AARS1P1, AC115622.1, AC110751.1, AC105383.1, R3HDM2P1, PCDH10, AC108052.1, AC105252.1, AC079380.1.
- chr5:12,297,399–13,250,662, 8 genes, copy number 5: RNU6-679P, AC106771.1, LINC01194, AC106794.2, AC106794.1, LINC02220, AC016553.1, RPS23P5.
- chr5:17,684,584–31,054,153, 116 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:69,424,849–94,707,466, 384 genes, copy number 5 (broad region; genes not listed).
- chr8:104,330,324–104,467,055, 1 gene, copy number 5 (within-gene range 4–5): DPYS.
- chr8:104,419,512–122,428,551, 157 genes, copy number 5 (broad region; genes not listed).
- chr8:135,457,456–138,497,261, 14 genes, copy number 5 (within-gene range 4–5): KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B.
- chr17:42,268,587–45,895,680, 221 genes, copy number 5–10 (within-gene range 3–10) (broad region; genes not listed).
- chr17:52,862,121–54,365,634, 10 genes, copy number 10 (within-gene range 3–10): LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B.
- chr17:54,477,796–59,281,343, 124 genes, copy number 5–6 (broad region; genes not listed).
- chr17:59,885,015–60,666,280, 39 genes, copy number 6: NDUFB8P2, RPS6KB1, RPS29P21, AC005702.1, RNFT1, TBC1D3P1-DHX40P1, RNFT1-DT, DHX40P1, TBC1D3P1, AC005702.5, AC005702.4, AC005702.3, HEATR6, MIR4737, AC005702.2, AC025048.4, WFDC21P, AC025048.6, AC025048.3, AC025048.2, AC025048.5, AC025048.7, AC025048.1, CA4, USP32, SCARNA20, AC104763.1, AC104763.2, H3P42, C17orf64, RPL12P38, APPBP2, AC011921.3, AC011921.1, AC011921.2, LINC01999, RPSAP66, PPM1D, RNU6-623P.
- chr17:60,696,313–60,749,046, 3 genes, copy number 6: RN7SL606P, AC110602.1, Y_RNA.
- chr17:62,231,470–62,754,973, 20 genes, copy number 6 (within-gene range 3–6): AC053481.3, AC053481.4, TBC1D3P2, AC053481.2, AC053481.1, EFCAB3, AC008026.2, RNU7-52P, RPS23P7, METTL2A, TLK2, AC008026.1, AC008026.3, AC080038.2, AC080038.1, MRC2, Y_RNA, AC080038.3, RNU6-446P, AC005821.1.
- chr17:63,773,603–64,662,307, 39 genes, copy number 7 (within-gene range 3–7): DDX42, FTSJ3, PSMC5, SMARCD2, TCAM1P, CSH2, GH2, AC040958.1, CSH1, AC127029.1, CSHL1, GH1, AC127029.3, CD79B, SCN4A, AC127029.2, PRR29-AS1, PRR29, ICAM2, ERN1, AC005803.1, SNHG25, SNORD104, AC025362.1, SNORA50C, TEX2, RPL31P57, PECAM1, Y_RNA, AC234063.1, MILR1, POLG2, ATP5MFP4, DDX5, MIR3064, MIR5047, CEP95, SMURF2, AC009994.1.
- chr17:67,224,303–70,180,044, 79 genes, copy number 6 (broad region; genes not listed).
- chr17:71,620,978–73,092,712, 19 genes, copy number 5: MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9, LINC00511, LINC02003, AC007639.1, RPL32P33, AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1.
- chr17:76,563,710–82,212,830, 237 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr19:17,951,293–21,594,628, 185 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr19:33,132,090–33,309,387, 12 genes, copy number 5: WDR88, LRP3, AC008738.1, AC008738.7, SLC7A10, AC008738.4, AC008738.6, AC008738.3, CEBPA, AC008738.5, CEBPA-DT, AC008738.2.
- chr19:42,268,537–43,363,172, 42 genes, copy number 5 (within-gene range 3–5): CIC, PAFAH1B3, PRR19, TMEM145, MEGF8, MIR8077, CNFN, LIPE-AS1, LIPE, AC011497.1, CXCL17, RNU4-60P, AC011497.2, CEACAM1, CEACAMP2, CEACAM8, CEACAMP1, CEACAMP5, RPS10P28, PSG3, PSG8, CEACAMP6, PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8, PSG2, CEACAMP9, AC005392.1, PSG5, PSG4, CEACAMP10, PSG9, CEACAMP11, CEACAMP4, AC005392.2, CD177.

Autosomal genes at a single copy (total copy number 1): 14,090. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
